Somatic mutation profile of tumor specimen HCM-CSHL-0184-C25-01A (aliquot HCM-CSHL-0184-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0184-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.3 years (28,240 days).
Specimen HCM-CSHL-0184-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e34ef06f-5333-46a5-8bf8-30d1354767c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0184-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0184-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7e3f62c-1c5b-4324-b869-7c84d04474d4

The open-access MAF lists 60 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, In Frame Del 1, 5'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 161/445 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 88/284 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757242670; called by muse, mutect2, varscan2
- APC | c.5369G>A p.R1790K | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1158503665, COSV57328312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTRC | c.860G>A p.R287K (on ENST00000370187 / NM_033637.4; = p.R251K on NM_003939.5) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as COSV64579603; called by muse, mutect2, varscan2
- CYP2R1 | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs782622230; called by muse, mutect2, varscan2
- EGFR | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 152/439 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1554348865, COSV104369002, COSV51766284; called by muse, mutect2, varscan2
- FLRT2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs745818091, COSV58145614; called by muse, varscan2
- GRB14 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 43/151 reads (28%) | catalogued as rs1457587748; called by muse, mutect2, varscan2
- KCNH2 | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs950543448, CD139906; called by muse, mutect2, varscan2
- KCTD9 | c.326A>C p.N109T | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as rs778794171; called by muse, mutect2, varscan2
- MUC16 | c.37207G>A p.E12403K | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.042); catalogued as rs1407929387, COSV67448438; called by muse, mutect2, varscan2
- NLRP3 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 39/554 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs76291085, COSV100275148; ClinVar: uncertain significance; called by muse, mutect2
- SERPINA3 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 52/590 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67586597; called by muse, mutect2
- SSU72 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 156/279 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs1023230253; called by muse, mutect2, varscan2
- TRIM37 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1480459291; called by muse, mutect2, varscan2
- WDR47 | c.1304G>A p.R435H (on ENST00000369962 / NM_001142551.2; = p.R436H on NM_014969.5) | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760204418, COSV100728346; called by muse, mutect2, varscan2
- WDR70 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs970163407, COSV99458142; called by muse, mutect2
- ZNF311 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs765712189, COSV101014142, COSV65853519; called by muse, mutect2, varscan2
- ZNF592 | c.3695C>T p.A1232V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as rs201671775; called by muse, mutect2, varscan2
- CDHR3 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- CTH | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 119/589 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- DIO1 | c.465A>C p.E155D | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- DOCK2 | c.1912A>G p.K638E | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- FMR1 | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- GFI1 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 161/424 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GRXCR2 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- GSTO2 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IPO4 | c.1895del p.F632Sfs*54 | Frame Shift Del (DEL) | VAF 67/251 reads (27%) | called by mutect2, pindel, varscan2
- KIF23 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP5 | c.5150C>T p.T1717I | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEC | c.13537_13578del p.K4513_E4526del (on ENST00000322810 / NM_201380.4; = p.K4403_E4416del on NM_000445.5) | In Frame Del (DEL) | VAF 36/324 reads (11%) | called by mutect2, pindel
- PLEC | c.1775A>T p.D592V (on ENST00000322810 / NM_201380.4; = p.D482V on NM_000445.5) | Missense Mutation (SNP) | VAF 66/935 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPL | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PPP2R1B | c.1684A>T p.I562F | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCUBE2 | c.2154G>A p.W718* (on ENST00000649792 / NM_001367977.2; = p.W563* on NM_001170690.2) | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- SLC12A4 | c.670T>G p.L224V | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TBC1D8B | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM201 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 8/211 reads (4%) | called by muse, mutect2
- TMEM221 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- WAPL | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- WASL | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZFHX4 | c.6640T>C p.S2214P | Missense Mutation (SNP) | VAF 111/259 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF285 | c.-41C>T | Splice Region (SNP) | VAF 52/220 reads (24%) | called by muse, mutect2, varscan2
- ZNRF1 | c.667del p.E223Nfs*35 | Frame Shift Del (DEL) | VAF 76/474 reads (16%) | called by mutect2, pindel, varscan2
- DESI2 | c.138T>G p.P46= | Silent (SNP) | VAF 46/226 reads (20%) | called by muse, mutect2, varscan2
- FLG2 | c.843T>A p.G281= | Silent (SNP) | VAF 63/208 reads (30%) | catalogued as COSV101165709; called by muse, mutect2, varscan2
- H1-2 | c.252C>T p.L84= | Silent (SNP) | VAF 84/336 reads (25%) | catalogued as rs1224166339, COSV59191386; called by muse, mutect2, varscan2
- MAN2A1 | c.1806T>C p.S602= | Silent (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.39420T>C p.P13140= | Silent (SNP) | VAF 24/269 reads (9%) | called by muse, mutect2
- PNP | c.765C>T p.A255= | Silent (SNP) | VAF 27/602 reads (4%) | called by muse, mutect2
- SERPINB2 | c.696A>G p.V232= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1902G>A p.P634= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as rs185965511, COSV68567514; called by muse, mutect2, varscan2
- TSHZ2 | c.1830G>A p.A610= | Silent (SNP) | VAF 84/155 reads (54%) | catalogued as rs147016688, COSV61587419; called by muse, mutect2, varscan2
- ZIC3 | c.252C>A p.A84= | Silent (SNP) | VAF 68/216 reads (31%) | called by muse, mutect2, varscan2
- AOAH | c.1600-1162G>T | Intron (SNP) | VAF 129/369 reads (35%) | called by muse, mutect2, varscan2
- CTSA | c.195-35C>T | Intron (SNP) | VAF 28/330 reads (8%) | called by muse, mutect2
- CTTN | c.679+10G>A | Intron (SNP) | VAF 43/163 reads (26%) | catalogued as rs764505525; called by muse, mutect2, varscan2
- GLB1L2 | c.-44G>A | 5'UTR (SNP) | VAF 67/251 reads (27%) | called by muse, mutect2, varscan2
- PTPA | chr9:129110981 C>T | 5'Flank (SNP) | VAF 58/224 reads (26%) | catalogued as rs113217898; called by muse, mutect2, varscan2
